Somatic mutation profile of tumor specimen MMRF_1718_1_BM_CD138pos (aliquot MMRF_1718_1_BM_CD138pos_T1_KBS5U_L04821) from MMRF case MMRF_1718, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 60.4 years (22,058 days).
Specimen MMRF_1718_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9c77e000-05f1-4d0a-9186-39620442b7fb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1718_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1718_1_PB_Whole_C3_KBS5U_L04833; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/731c9ba9-3be3-45dd-a465-d08a269497c3

The open-access MAF lists 53 somatic variants for this specimen: 26 protein-altering or splice-affecting, 9 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 9, 3'UTR 9, Intron 5, 3'Flank 2, Frame Shift Del 1, 5'Flank 1, RNA 1, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 53/260 reads (20%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 64/282 reads (23%) | hotspot (GDC flag); catalogued as rs397516436, CM951226, COSV52665560, COSV52740638, COSV52746781, COSV52782151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACOT12 | c.1320T>G p.C440W | Missense Mutation (SNP) | VAF 68/302 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV56895180; called by muse, mutect2, varscan2
- ACVR1B | c.1451G>A p.R484H | Missense Mutation (SNP) | VAF 63/306 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1460557299, COSV57776372, COSV57780549; called by muse, mutect2, varscan2
- AURKB | c.443G>A p.R148K | Missense Mutation (SNP) | VAF 35/183 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV60246538; called by muse, mutect2, varscan2
- BIRC6 | c.8585C>T p.S2862L | Missense Mutation (SNP) | VAF 72/287 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as rs747507337, COSV70206564; called by muse, mutect2, varscan2
- CYP4F3 | c.394C>A p.L132M | Missense Mutation (SNP) | VAF 37/256 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1568394600, COSV99658824; called by muse, mutect2, varscan2
- EIF4A2 | c.245G>A p.G82D | Missense Mutation (SNP) | VAF 91/376 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99961255; called by muse, mutect2, varscan2
- IGHV1-69D | c.281C>T p.S94F | Missense Mutation (SNP) | VAF 95/820 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.207); catalogued as rs1245187933; called by muse, varscan2
- IGKJ2 | c.34A>G p.I12V | Missense Mutation (SNP) | VAF 46/282 reads (16%) | catalogued as rs546722952; called by muse, varscan2
- IGLV3-1 | c.71C>G p.T24S | Missense Mutation (SNP) | VAF 47/208 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.678); catalogued as rs186574328; called by muse, varscan2
- SPAG16 | c.1583T>G p.F528C | Missense Mutation (SNP) | VAF 62/257 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV59108613; called by muse, mutect2, varscan2
- TLCD3A | c.353G>A p.R118H | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.989); catalogued as rs776783244; called by muse, varscan2
- TMEM132B | c.1043C>T p.T348M | Missense Mutation (SNP) | VAF 43/195 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.07); catalogued as rs201518513; called by muse, mutect2, varscan2
- ACAP3 | c.140G>A p.G47D | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, varscan2
- C9 | c.226A>G p.K76E | Missense Mutation (SNP) | VAF 25/193 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- ISG20 | c.32A>G p.D11G | Missense Mutation (SNP) | VAF 46/226 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KNG1 | c.1453C>T p.H485Y | Missense Mutation (SNP) | VAF 42/178 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.01); called by muse, mutect2
- LIPT2 | c.247A>G p.T83A | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.414); called by muse, mutect2, varscan2
- MACF1 | c.15806T>C p.I5269T (on ENST00000372915; = p.I3202T on NM_012090.5) | Missense Mutation (SNP) | VAF 57/307 reads (19%) | called by muse, mutect2, varscan2
- MYH2 | c.3871+2T>G p.X1291_splice | Splice Site (SNP) | VAF 24/129 reads (19%) | called by muse, mutect2, varscan2
- NRCAM | c.3545T>C p.L1182S (on ENST00000379028 / NM_001371124.1; = p.L1061S on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 80/313 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLA2R1 | c.1564C>A p.H522N | Missense Mutation (SNP) | VAF 48/241 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PRRC2B | c.2467C>G p.Q823E | Missense Mutation (SNP) | VAF 54/321 reads (17%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- SPAG17 | c.3059A>G p.H1020R | Missense Mutation (SNP) | VAF 26/154 reads (17%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- TENT5C | c.431_432del p.K144Sfs*6 | Frame Shift Del (DEL) | VAF 66/284 reads (23%) | called by mutect2, pindel*, varscan2
- EVI5 | c.2295G>A p.S765= | Silent (SNP) | VAF 89/358 reads (25%) | catalogued as rs61735641; called by muse, mutect2, varscan2
- FAM222B | c.489C>G p.T163= | Silent (SNP) | VAF 10/76 reads (13%) | called by muse, mutect2
- GRM5 | c.510T>A p.I170= | Silent (SNP) | VAF 90/532 reads (17%) | called by muse, mutect2, varscan2
- IGLL5 | c.51C>T p.G17= | Silent (SNP) | VAF 32/117 reads (27%) | catalogued as rs1176686017; called by muse, mutect2, varscan2
- OR2M3 | c.513T>G p.S171= | Silent (SNP) | VAF 57/235 reads (24%) | called by muse, mutect2, varscan2
- OR5M11 | c.681C>A p.I227= | Silent (SNP) | VAF 44/274 reads (16%) | called by muse, mutect2, varscan2
- POLR1A | c.3093C>T p.F1031= | Silent (SNP) | VAF 60/236 reads (25%) | called by muse, mutect2, varscan2
- TTN | c.38538T>C p.S12846= (on ENST00000591111; = p.S5422= on NM_003319.4) | Silent (SNP) | VAF 67/283 reads (24%) | catalogued as COSV59943874; called by muse, mutect2, varscan2
- VN1R4 | c.615A>C p.I205= | Silent (SNP) | VAF 19/140 reads (14%) | catalogued as rs142023427; called by muse, mutect2
- AP000769.5 | chr11:65499095 C>T | 5'Flank (SNP) | VAF 36/112 reads (32%) | called by muse, mutect2, varscan2
- C1QTNF9B | c.167-371C>G | Intron (SNP) | VAF 30/120 reads (25%) | catalogued as rs3864973, COSV65944538; called by muse, mutect2, varscan2
- CADM2 | chr3:86068796 A>G | 3'Flank (SNP) | VAF 34/142 reads (24%) | called by muse, mutect2
- ELOVL6 | c.*1375G>T | 3'UTR (SNP) | VAF 52/213 reads (24%) | called by muse, mutect2, varscan2
- FAT3 | c.*2082A>C | 3'UTR (SNP) | VAF 140/366 reads (38%) | called by muse, mutect2, varscan2
- FLYWCH1 | c.-73-6730G>A | Intron (SNP) | VAF 12/54 reads (22%) | catalogued as rs927221799; called by muse, mutect2
- GABRA1 | c.-15-243G>A | Intron (SNP) | VAF 30/132 reads (23%) | called by muse, mutect2, varscan2
- GRM7 | c.2452-43789G>T | Intron (SNP) | VAF 91/410 reads (22%) | called by muse, mutect2, varscan2
- HOXD3 | chr2:176173827 G>A | 3'Flank (SNP) | VAF 32/160 reads (20%) | called by muse, mutect2, varscan2
- LRATD1 | c.*4528A>C | 3'UTR (SNP) | VAF 37/182 reads (20%) | called by muse, mutect2, varscan2
- PPP1R12A | c.*757del | 3'UTR (DEL) | VAF 32/158 reads (20%) | catalogued as rs370457117; called by mutect2, varscan2
- RABGAP1 | c.1908+72A>G | Intron (SNP) | VAF 14/76 reads (18%) | called by muse, mutect2
- SLC6A10P | n.1275A>G | RNA (SNP) | VAF 14/79 reads (18%) | called by muse, mutect2
- SOS1 | c.*390T>A | 3'UTR (SNP) | VAF 35/132 reads (27%) | catalogued as rs931006072, COSV101217191; called by muse, mutect2, varscan2
- SYNPO | c.*3809A>T | 3'UTR (SNP) | VAF 52/178 reads (29%) | called by muse, mutect2, varscan2
- TRIM52 | c.*558A>G | 3'UTR (SNP) | VAF 76/185 reads (41%) | catalogued as rs960324942; called by muse, mutect2, varscan2
- TSPAN9 | c.*78C>T | 3'UTR (SNP) | VAF 54/262 reads (21%) | catalogued as rs551137676; called by muse, mutect2, varscan2
- UNC5D | c.*2029T>G | 3'UTR (SNP) | VAF 61/226 reads (27%) | called by muse, mutect2, varscan2
